Somatic mutation profile of tumor specimen MP2PRT-PAVUJV-TMP1-A (aliquot MP2PRT-PAVUJV-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVUJV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,202 days).
Specimen MP2PRT-PAVUJV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d206acd-9493-43e9-a54b-9acd59524797.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUJV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUJV-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61d1f1dc-5d1e-4a09-9e4a-4547a2f9787b

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADD2 | c.764A>G p.D255G | Missense Mutation (SNP) | VAF 50/407 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as COSV52456903; called by muse, mutect2, varscan2
- AFF2 | c.3053C>A p.T1018N | Missense Mutation (SNP) | VAF 57/563 reads (10%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.486); catalogued as COSV54004783; called by muse, mutect2, varscan2
- ANK3 | c.7501C>T p.R2501W | Missense Mutation (SNP) | VAF 40/373 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.543); catalogued as rs759280618, COSV55073423; called by muse, mutect2, varscan2
- ATRX | c.3043G>A p.G1015S | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV64881863; called by muse, mutect2, varscan2
- FAM83B | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 49/331 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs368876321; called by muse, mutect2, varscan2
- GLIS3 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60932488; called by mutect2, varscan2
- GNB1 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66101788; called by muse, mutect2, varscan2
- IGBP1P2 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 46/400 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.868); catalogued as rs568899194, COSV53621351; called by muse, mutect2, varscan2
- MYO16 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 38/468 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs201650171, COSV51782521; called by muse, mutect2
- AC099489.1 | c.9483G>A p.P3161= | Silent (SNP) | VAF 37/325 reads (11%) | catalogued as rs1350141831; called by muse, mutect2, varscan2
- RAPH1 | c.3297A>G p.P1099= | Silent (SNP) | VAF 11/398 reads (3%) | called by muse, mutect2
